Somatic mutation profile of tumor specimen 0DP8O8 from CCDI case PBCCZT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant, uncertain whether primary or metastatic; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.9 years (5,069 days).
Specimen 0DP8O8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 890f4fb4-0ee1-4dec-8f38-e6374767cf84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP8NZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed3d0a90-2b95-45ba-8fc0-3724b4184ec3

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 303/986 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- PDZD2 | c.6400C>T p.R2134C | Missense Mutation (SNP) | VAF 171/522 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as rs374787609, COSV56854930; called by muse, mutect2, varscan2
- SMPD1 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 290/869 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV54970629; called by muse, mutect2, varscan2
- OR4A5 | c.75A>T p.L25F | Missense Mutation (SNP) | VAF 385/1250 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SGO2 | c.2383C>A p.Q795K | Missense Mutation (SNP) | VAF 43/1295 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.272); called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 20/301 reads (7%) | catalogued as rs1167537044; called by muse, mutect2
- SLC5A12 | c.969C>T p.V323= | Silent (SNP) | VAF 472/1454 reads (32%) | catalogued as COSV54821453; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 15/351 reads (4%) | called by muse, mutect2
- PRKCB | c.289-52G>A | Intron (SNP) | VAF 37/105 reads (35%) | catalogued as rs1393914843; called by muse, mutect2, varscan2
